Somatic mutation profile of tumor specimen MMRF_2313_1_BM_CD138pos (aliquot MMRF_2313_1_BM_CD138pos_T1_KHS5U_L11050) from MMRF case MMRF_2313, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.4 years (19,493 days).
Specimen MMRF_2313_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1955e3da-e3ef-44de-8167-9bda5c86e5a9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2313_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2313_1_PB_WBC_C2_KHS5U_L11049; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d8161ec-c8b1-40ca-b054-c958c08756b7

The open-access MAF lists 91 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, 3'UTR 18, Intron 16, Silent 12, 5'UTR 6, 5'Flank 5, 3'Flank 2, RNA 2, Splice Site 1, Frame Shift Del 1, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COG6 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs752232501; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 68/98 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SLC6A3 | c.1269+1G>A p.X423_splice | Splice Site (SNP) | VAF 28/119 reads (24%) | catalogued as rs431905504, CS121209, CS143018; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DUSP4 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 62/142 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.154); catalogued as rs919580482, COSV99529934; called by muse, mutect2, varscan2
- GNPAT | c.1615G>A p.G539S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1185596649; called by muse, mutect2, varscan2
- HNRNPF | c.811A>C p.M271L | Missense Mutation (SNP) | VAF 80/157 reads (51%) | SIFT tolerated (0.25); PolyPhen benign (0.026); catalogued as COSV100562924; called by muse, mutect2, varscan2
- IGHV3-23 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 40/253 reads (16%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.022); catalogued as rs377421865; called by muse, varscan2
- KCNG1 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV65368016; called by muse, varscan2
- KIAA1210 | c.136T>G p.C46G | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV68180082; called by muse, mutect2, varscan2
- MCTP2 | c.2189G>C p.S730T | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV100752250; called by muse, mutect2, varscan2
- MYOZ1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV63771864; called by muse, mutect2, varscan2
- OR51I1 | c.820G>T p.V274F | Missense Mutation (SNP) | VAF 93/366 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.826); catalogued as rs772504296; called by muse, mutect2, varscan2
- SSC5D | c.4445T>G p.V1482G | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs778848198; called by muse, mutect2, varscan2
- TAGLN3 | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as rs1310462198; called by muse, varscan2
- ADAMTS9 | c.5625C>G p.S1875R | Missense Mutation (SNP) | VAF 88/351 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- APEX2 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 73/75 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ARID4A | c.1063G>A p.G355R | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARL16 | c.76T>C p.C26R | Missense Mutation (SNP) | VAF 147/469 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- CABIN1 | c.5008G>A p.G1670R | Missense Mutation (SNP) | VAF 62/131 reads (47%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CHRNA3 | c.921C>G p.Y307* | Nonsense Mutation (SNP) | VAF 65/193 reads (34%) | called by muse, mutect2, varscan2
- FAM234B | c.1124del p.E375Gfs*16 | Frame Shift Del (DEL) | VAF 38/61 reads (62%) | called by mutect2, pindel, varscan2
- H2BC12 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- ITGA4 | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- MCM7 | c.1982T>C p.I661T | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MET | c.953A>T p.Q318L | Missense Mutation (SNP) | VAF 61/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SCYL3 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 78/154 reads (51%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.953); called by mutect2, varscan2
- SLC15A3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM4 | c.51C>G p.D17E | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT tolerated, low confidence (0.81); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TNMD | c.574T>A p.S192T | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.6014G>A p.G2005D | Missense Mutation (SNP) | VAF 122/194 reads (63%) | SIFT tolerated (0.89); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADGRL3 | c.1932T>G p.A644= (on ENST00000506720 / NM_001322402.2; = p.A576= on NM_015236.6) | Silent (SNP) | VAF 83/198 reads (42%) | catalogued as COSV63368369; called by muse, mutect2, varscan2
- CDK5RAP3 | c.492C>T p.S164= | Silent (SNP) | VAF 52/134 reads (39%) | called by muse, mutect2, varscan2
- EDNRB | c.315G>A p.L105= (on ENST00000377211 / NM_001201397.1; = p.L15= on NM_000115.5) | Silent (SNP) | VAF 33/93 reads (35%) | catalogued as COSV100526537; called by muse, mutect2, varscan2
- EYS | c.8565C>T p.P2855= (on ENST00000370621 / NM_001292009.1; = p.P2834= on NM_001142800.2) | Silent (SNP) | VAF 61/216 reads (28%) | called by muse, mutect2, varscan2
- FAT4 | c.13626G>A p.E4542= | Silent (SNP) | VAF 59/152 reads (39%) | catalogued as COSV58682041; called by muse, mutect2, varscan2
- FBXO2 | c.159G>C p.P53= | Silent (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- FRAS1 | c.9501C>T p.P3167= | Silent (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2
- LZTS3 | c.1158G>A p.Q386= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs1483379667, COSV100232420; called by muse, mutect2
- MAMDC2 | c.810C>A p.G270= | Silent (SNP) | VAF 27/91 reads (30%) | called by muse, mutect2, varscan2
- TDRD6 | c.5799A>G p.E1933= | Silent (SNP) | VAF 118/176 reads (67%) | called by muse, mutect2, varscan2
- TNIK | c.1701G>A p.R567= | Silent (SNP) | VAF 68/177 reads (38%) | called by muse, mutect2, varscan2
- UGGT2 | c.855T>C p.D285= | Silent (SNP) | VAF 23/47 reads (49%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149758 C>T | 5'Flank (SNP) | VAF 36/44 reads (82%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+82837A>G | Intron (SNP) | VAF 16/54 reads (30%) | called by muse, varscan2
- ANKRD40CL | chr17:50767506 A>G | 5'Flank (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- ANP32E | c.-160C>T | 5'UTR (SNP) | VAF 118/285 reads (41%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.*964T>C | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- CCDC89 | c.*488A>T | 3'UTR (SNP) | VAF 17/68 reads (25%) | called by mutect2, varscan2
- CCNL1 | c.-7T>C | 5'UTR (SNP) | VAF 70/241 reads (29%) | called by muse, mutect2, varscan2
- CDH9 | c.999+86T>A | Intron (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- CGGBP1 | c.-23-748T>C | Intron (SNP) | VAF 13/67 reads (19%) | called by muse, mutect2, varscan2
- CHMP1B | c.*1681C>T | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- CXCL14 | c.-187G>A | 5'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- DDX43 | c.306+20C>T | Intron (SNP) | VAF 20/87 reads (23%) | catalogued as rs770499670; called by muse, mutect2, varscan2
- DDX46 | c.*470A>C | 3'UTR (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- EIF3FP3 | n.123G>A | RNA (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- ERGIC1 | c.376-3587G>A | Intron (SNP) | VAF 89/307 reads (29%) | called by muse, mutect2, varscan2
- FIGN | c.*4398G>C | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- GIGYF1 | c.-349G>T | 5'UTR (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- GLDN | c.364-183G>A | Intron (SNP) | VAF 40/66 reads (61%) | catalogued as rs1172943728; called by muse, mutect2, varscan2
- GPX2 | chr14:64943943 A>C | 5'Flank (SNP) | VAF 46/77 reads (60%) | called by muse, mutect2, varscan2
- KCNJ8 | c.375-36C>T | Intron (SNP) | VAF 22/25 reads (88%) | called by muse, mutect2, varscan2
- KCNV1 | c.*235G>A | 3'UTR (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- KTN1 | chr14:55576832 A>T | 5'Flank (SNP) | VAF 25/52 reads (48%) | called by muse, mutect2, varscan2
- LAMC3 | c.*345C>T | 3'UTR (SNP) | VAF 20/69 reads (29%) | catalogued as rs1223565495; called by muse, mutect2, varscan2
- LTB | c.163-94A>C | Intron (SNP) | VAF 164/554 reads (30%) | catalogued as rs558947212; called by muse, mutect2, varscan2
- MAP1B | c.*3390C>T | 3'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- MEIOC | c.*887del | 3'UTR (DEL) | VAF 25/104 reads (24%) | catalogued as rs909310684; called by mutect2, pindel, varscan2
- MPHOSPH9 | chr12:123152642 C>T | 3'Flank (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- MYO1D | c.1296+230A>T | Intron (SNP) | VAF 43/140 reads (31%) | called by muse, mutect2, varscan2
- NAA50 | c.-220A>C | 5'UTR (SNP) | VAF 77/125 reads (62%) | called by muse, mutect2, varscan2
- NR5A2 | c.1110+8980del | Intron (DEL) | VAF 13/15 reads (87%) | called by mutect2, varscan2
- NRXN1 | c.832+195T>G | Intron (SNP) | VAF 6/8 reads (75%) | called by muse, mutect2
- OLAH | c.302+185dup | Intron (INS) | VAF 14/35 reads (40%) | catalogued as rs976833831; called by mutect2, varscan2
- OOSP2 | c.*71G>A | 3'UTR (SNP) | VAF 33/187 reads (18%) | called by muse, mutect2, varscan2
- PCDHAC1 | c.*1438A>C | 3'UTR (SNP) | VAF 85/150 reads (57%) | called by muse, mutect2, varscan2
- PPIAP59 | n.1C>T | RNA (SNP) | VAF 54/132 reads (41%) | catalogued as rs1011978157; called by muse, mutect2, varscan2
- PPM1B | chr2:44234544 A>C | 3'Flank (SNP) | VAF 19/35 reads (54%) | catalogued as rs939421152; called by muse, mutect2, varscan2
- PTH2R | c.-5C>A | 5'UTR (SNP) | VAF 42/81 reads (52%) | catalogued as COSV99782345; called by muse, mutect2, varscan2
- RPL36 | c.93+166C>T | Intron (SNP) | VAF 29/90 reads (32%) | catalogued as rs1204451813; called by muse, mutect2, varscan2
- SEMA5A | c.*1529C>T | 3'UTR (SNP) | VAF 22/104 reads (21%) | called by muse, mutect2, varscan2
- SERPINA3 | c.644-200T>G | Intron (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- SOX21 | c.*838C>T | 3'UTR (SNP) | VAF 24/49 reads (49%) | called by muse, mutect2, varscan2
- SPINK6 | chr5:148202803 C>G | 5'Flank (SNP) | VAF 23/80 reads (29%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+49216T>G | Intron (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- USP35 | c.*241G>A | 3'UTR (SNP) | VAF 65/296 reads (22%) | catalogued as rs372651017; called by muse, mutect2, varscan2
- ZBTB44 | c.*2852C>T | 3'UTR (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2, varscan2
- ZFP91 | c.*3009A>G | 3'UTR (SNP) | VAF 33/96 reads (34%) | catalogued as rs1043124466; called by muse, mutect2, varscan2
- ZNF512 | c.*867A>G | 3'UTR (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- ZNF812P | n.544+2391G>A | Intron (SNP) | VAF 126/214 reads (59%) | called by muse, mutect2, varscan2
- ZSCAN25 | c.*376G>A | 3'UTR (SNP) | VAF 67/224 reads (30%) | called by muse, mutect2, varscan2
